Somatic mutation profile of tumor specimen TCGA-FE-A232-01A (aliquot TCGA-FE-A232-01A-11D-A14W-08) from TCGA case TCGA-FE-A232, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 44.6 years (16,280 days).
Specimen TCGA-FE-A232-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8a3fef86-8257-4a16-975f-9d9dd0e39583.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FE-A232-10A (Blood Derived Normal), aliquot TCGA-FE-A232-10A-01D-A14W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ac9781c0-6ac3-42de-ba8a-8a635f5a27a3

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- ASH1L | c.278C>G p.A93G | Missense Mutation (SNP) | VAF 8/244 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as COSV64214055; called by muse, mutect2
- CHST10 | c.844C>T p.H282Y | Missense Mutation (SNP) | VAF 21/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV51807742; called by muse, mutect2, varscan2
- KIF4B | c.49C>T p.R17C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70530234; called by muse, mutect2, varscan2
- ORC1 | c.1409C>T p.A470V | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as COSV100856547; called by muse, mutect2
- RBM17 | c.557A>C p.K186T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.076); catalogued as COSV65914962; called by muse, mutect2, varscan2
- SCAF4 | c.688A>G p.I230V | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV54583478; called by muse, mutect2, varscan2
- SLC34A2 | c.1864T>C p.C622R | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV101158185; called by muse, mutect2, varscan2
- CACNA1C | c.1217+325A>G | Intron (SNP) | VAF 12/30 reads (40%) | catalogued as COSV59774275; called by muse, mutect2, varscan2
